Surgical pathology report (de-identified scan), TCGA case TCGA-W5-AA2M, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Mayo Clinic Rochester, specimen TCGA-W5-AA2M-01A (Primary Tumor).

Male

Surgery Date:

DIAGNOSIS:

Liver, right lobe, resection: Grade 2 (of 4) cholangiocarcinoma forming a 2.4 x 2.3 x 2.0 cm mass around the right extrahepatic common hepatic bile duct in the hilar region. The tumor extends into the liver and periductal soft tissues including the serosa of the gallbladder. The surgical margins are negative. Multiple (9) hepatoduodenal lymph nodes are benign.

Soft tissue, distal bile duct margin, excision: Bile duct; negative for malignancy.

ICD-O-3

Cholangiocarcinoma 8160/3

Site: Bile duct NOS C24.0

Extrahepatic bile duct C24.0

yo 5/8/14

Source: NCI Genomic Data Commons file 3d05c247-5f1d-4baf-aeee-53c0c012f74f (TCGA-W5-AA2M.039FBA2F-C258-4518-809B-82D3005929B5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).